Gene-level copy-number profile of tumor specimen HTMCP-03-06-02194-01A from CGCI case HTMCP-03-06-02194, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB.
Specimen HTMCP-03-06-02194-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd72d3c0-aac1-47dc-829f-c776b08e916a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02194-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,396 have no estimate.
https://portal.gdc.cancer.gov/files/d39e5b91-53f8-4831-b5ab-46c00320d462

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 5; copy number 2: 8,360; copy number 3: 21,914; copy number 4: 14,734; copy number 5: 8,482; copy number 6: 1,983; copy number 7: 1,963; copy number 8: 487; copy number 9: 13; copy number 10: 14; copy number 11: 76; copy number 12: 124; copy number 13: 5; copy number 14: 5; copy number 15: 2; copy number 16: 11; copy number 19: 2; copy number 22: 4; copy number 23: 15; copy number 28: 6; copy number 32: 3; copy number 34: 9; copy number 38: 2; copy number 67: 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr21:9,053,122–9,129,752, 4 genes: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,725 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:106,325,737–128,153,914, 391 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr3:128,879,596–198,123,232, 1,200 genes, copy number 7–8 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 7–8 (broad region; genes not listed).
- chr5:131,155,383–131,224,468, 2 genes, copy number 15: HINT1, LYRM7.
- chr5:177,682,294–177,713,969, 1 gene, copy number 7 (within-gene range 6–7): AC138819.1.
- chr6:4,599,287–4,611,919, 2 genes, copy number 67: AL034376.1, KU-MEL-3.
- chr6:6,901,022–7,881,728, 22 genes, copy number 23–34 (within-gene range 5–34): AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6.
- chr6:8,102,711–9,294,133, 7 genes, copy number 19–38: AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1, AL137220.1.
- chr6:38,168,451–39,725,408, 24 genes, copy number 8: BTBD9, AL033518.1, BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5, KCNK17, KCNK16, KIF6, AL136087.1, E2F4P1, RNU1-54P.
- chr7:38,239,580–38,340,998, 16 genes, copy number 7: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr8:38,223,957–38,560,939, 14 genes, copy number 9–11: AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1.
- chr10:38,356,380–38,466,176, 6 genes, copy number 28: HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1.
- chr10:38,635,908–38,719,229, 4 genes, copy number 12–34: PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5.
- chr11:103,109,410–103,479,863, 9 genes, copy number 7: DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr14:20,891,399–20,936,255, 4 genes, copy number 7: RNASE3, AL355922.4, AL355922.3, AL355922.1.
- chr14:21,918,188–22,488,652, 64 genes, copy number 7–11 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 11: TRAC.
- chr18:20,946,906–21,870,953, 23 genes, copy number 12–22 (within-gene range 2–22): ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2.
- chr19:30,219,666–30,228,715, 1 gene, copy number 8 (within-gene range 4–8): AC005597.1.
- chr19:31,787,148–32,719,595, 19 genes, copy number 8–10: RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2.
- chr19:34,677,639–36,535,235, 131 genes, copy number 8–16 (within-gene range 4–16) (broad region; genes not listed).
- chr19:38,303,558–38,317,273, 1 gene, copy number 8 (within-gene range 6–8): YIF1B.
- chr19:38,319,845–40,122,168, 104 genes, copy number 8–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
